Somatic mutation profile of tumor specimen MP2PRT-PATEUZ-TMP1-A (aliquot MP2PRT-PATEUZ-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATEUZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (856 days).
Specimen MP2PRT-PATEUZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d27d77a9-ebac-4b64-8bd5-a7de3f6529d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATEUZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATEUZ-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09401004-510d-49ad-9791-a337749a82ac

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, In Frame Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B2 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 26/638 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1423976084, COSV59495710; called by muse, mutect2
- CPM | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764491691; called by muse, mutect2, varscan2
- IKZF1 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 133/548 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58785061; called by muse, mutect2, varscan2
- LRP1B | c.7556G>A p.G2519E | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV67250665; called by muse, mutect2
- NRAS | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 111/418 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54738004, COSV54746465; called by muse, mutect2, varscan2
- DOCK5 | c.1720-1G>T p.X574_splice | Splice Site (SNP) | VAF 96/243 reads (40%) | called by muse, mutect2, varscan2
- IGHV1-58 | c.348_349insAGACACTTG p.A116_A117insRHL | In Frame Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- KANK4 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 36/599 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- MTRNR2L13 | c.51C>G p.D17E | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); called by muse, mutect2
- SLC22A15 | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 141/443 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRAJ28 | c.1_5delinsGGCCCGGT p.Y2delinsPG | In Frame Ins (INS) | VAF 92/384 reads (24%) | called by pindel, varscan2*
- MYADML2 | c.543G>A p.A181= | Silent (SNP) | VAF 31/808 reads (4%) | catalogued as rs1195855412; called by muse, mutect2
- SCUBE2 | c.1830C>T p.T610= | Silent (SNP) | VAF 84/300 reads (28%) | catalogued as rs753492495; called by muse, mutect2, varscan2
